Somatic mutation profile of tumor specimen TCGA-AX-A1CR-01A (aliquot TCGA-AX-A1CR-01A-12D-A135-09) from TCGA case TCGA-AX-A1CR, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 70.7 years (25,812 days).
Specimen TCGA-AX-A1CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) abe1138d-7a29-4cd0-a9e5-3d11dd3d424d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1CR-10A (Blood Derived Normal), aliquot TCGA-AX-A1CR-10A-01W-A14P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/55678169-02c5-4a49-a0da-c5b8d25a5a24

The open-access MAF lists 49 somatic variants for this specimen: 40 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 7, Frame Shift Del 2, Splice Site 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1394G>T p.R465L (on ENST00000281708 / NM_001349798.2; = p.R385L on NM_018315.5) | Missense Mutation (SNP) | VAF 17/63 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.746G>C p.R249T | Missense Mutation (SNP) | VAF 39/49 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- AFM | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.339); catalogued as COSV99888685; called by muse, mutect2, varscan2
- AS3MT | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.098); catalogued as COSV100185643; called by muse, mutect2, varscan2
- ATP13A1 | c.997C>A p.L333M | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.229); catalogued as COSV99365982; called by muse, mutect2, varscan2
- BBS9 | c.1732A>C p.M578L (on ENST00000242067 / NM_001348036.1; = p.M538L on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99627368; called by muse, mutect2, varscan2
- BTN3A3 | c.1588C>T p.H530Y | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99764837; called by muse, mutect2
- C22orf31 | c.152T>G p.I51S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.088); catalogued as COSV53311208, COSV99326314; called by muse, mutect2, varscan2
- C4BPA | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.048); catalogued as rs370737185; called by muse, mutect2, varscan2
- CD55 | c.289A>T p.S97C | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100132373; called by muse, varscan2
- CLDN18 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs766478219, COSV100648235; called by muse, mutect2, varscan2
- CSMD1 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as COSV101218850; called by muse, mutect2, varscan2
- CSMD3 | c.6406G>A p.D2136N (on ENST00000297405 / NM_001363185.1; = p.D2032N on NM_052900.3) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.649); catalogued as COSV99827675, COSV99830696; called by muse, mutect2, varscan2
- DOP1B | c.5161G>A p.D1721N | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.964); catalogued as rs140282403; called by muse, mutect2, varscan2
- FGFR2 | c.1447C>G p.L483V | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV100335976; called by muse, mutect2, varscan2
- GJA10 | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.168); catalogued as COSV101005321; called by muse, mutect2, varscan2
- HPRT1 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV100053160; called by muse, mutect2, varscan2
- KCNH1 | c.2301G>C p.E767D (on ENST00000271751 / NM_172362.3; = p.E740D on NM_002238.4) | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV55105065, COSV99658466; called by muse, mutect2, varscan2
- KIF18B | c.784T>C p.S262P | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100191967; called by muse, mutect2, varscan2
- LAMC2 | c.1613G>A p.C538Y | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757195480, COSV99917304; called by muse, mutect2, varscan2
- LMAN2 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763454602, COSV57426306; called by muse, mutect2, varscan2
- LRFN5 | c.1012G>A p.D338N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.012); catalogued as COSV99983193; called by muse, mutect2, varscan2
- NAP1L2 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.935); catalogued as COSV100999194; called by muse, mutect2, varscan2
- OR6B3 | c.229A>T p.I77F | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV100097123; called by muse, mutect2, varscan2
- PAOX | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.013); catalogued as rs1037506942, COSV53375785; called by muse, mutect2, varscan2
- PCDHGB7 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.34); catalogued as rs761442517, COSV99535187; called by muse, mutect2, varscan2
- PDE10A | c.744+2T>C p.X248_splice | Splice Site (SNP) | VAF 12/26 reads (46%) | catalogued as rs1562460095, COSV100604923; called by muse, mutect2, varscan2
- PLEKHA4 | c.1534G>A p.V512M | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs200074374, COSV99612341; called by muse, mutect2, varscan2
- RUNX1T1 | c.1538A>G p.E513G (on ENST00000265814 / NM_001198628.1; = p.E486G on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99750994; called by muse, mutect2, varscan2
- SLC38A5 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs782419721, COSV100476447; called by muse, mutect2, varscan2
- SMARCAL1 | c.1831C>T p.R611C | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD141428, COSV61920690; called by muse, mutect2, varscan2
- SMG1 | c.1330A>T p.N444Y | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.462); catalogued as COSV101245594; called by muse, mutect2, varscan2
- TBXT | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs775012230, COSV51616284; called by muse, mutect2, varscan2
- TCF7 | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.184); catalogued as COSV100389870; called by muse, mutect2, varscan2
- TTN | c.77740C>T p.P25914S (on ENST00000591111; = p.P18490S on NM_003319.4) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | PolyPhen benign (0.012); catalogued as COSV100604463; called by muse, mutect2, varscan2
- XIRP2 | c.8825G>A p.R2942H (on ENST00000628543; = p.R3117H on NM_152381.6) | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV54684198, COSV54687421, COSV54705186; called by muse, mutect2, varscan2
- ZNF648 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.011); catalogued as COSV100374512; called by muse, mutect2, varscan2
- ZNF99 | c.2062C>G p.H688D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.292); catalogued as COSV101233785, COSV68056322; called by muse, mutect2, varscan2
- ARHGAP35 | c.1632del p.L545* | Frame Shift Del (DEL) | VAF 20/28 reads (71%) | called by mutect2, pindel*, varscan2
- HGSNAT | c.1752del p.G585Afs*15 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | called by mutect2, pindel*, varscan2
- CORO7 | c.1014C>T p.I338= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs772271708, COSV99227461; called by muse, mutect2
- CPB2 | c.168G>A p.P56= | Silent (SNP) | VAF 31/63 reads (49%) | catalogued as rs374272287; called by muse, mutect2, varscan2
- DLGAP2 | c.2916C>T p.N972= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs368740931; called by muse, mutect2, varscan2
- MAP3K19 | c.3822C>T p.A1274= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs777421257, COSV100208380; called by muse, mutect2, varscan2
- PNLIPRP1 | c.31C>T p.L11= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV62611121; called by muse, mutect2
- PPFIA3 | c.1263G>A p.K421= | Silent (SNP) | VAF 17/28 reads (61%) | catalogued as COSV100494831; called by muse, mutect2, varscan2
- PRDM9 | c.1101C>T p.I367= | Silent (SNP) | VAF 38/101 reads (38%) | catalogued as COSV99690220; called by muse, mutect2, varscan2
- AL359922.1 | c.348-35120C>G | Intron (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100845126; called by muse, mutect2, varscan2
- SNORD115-26 | n.66G>A | RNA (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
